Somatic mutation profile of tumor specimen TCGA-25-2396-01A (aliquot TCGA-25-2396-01A-01W-0799-08) from TCGA case TCGA-25-2396, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.6 years (26,145 days).
Specimen TCGA-25-2396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1dd810c-b23a-4482-a14a-3f4e57f9fb98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2396-10A (Blood Derived Normal), aliquot TCGA-25-2396-10A-01D-0704-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1215aa40-c9f6-40d4-86f7-e1f8a7adcc19

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 22, Silent 13, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 178/208 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs760243110, COSV53718017; called by muse, mutect2
- ACACB | c.5713G>A p.V1905M | Missense Mutation (SNP) | VAF 379/638 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs182648370; called by muse, mutect2, varscan2
- ANKRD26 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 88/393 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); catalogued as rs1169989924, COSV65774032; called by muse, mutect2, varscan2
- AP1G2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756362823, COSV58110195; called by muse, mutect2, varscan2
- ARID4A | c.2605A>G p.I869V | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs748437296, COSV62162019, COSV62163928, COSV62166290; called by muse, mutect2, varscan2
- ASCC2 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 67/1801 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs766214866, COSV57073839; called by muse, mutect2
- ASPM | c.7304T>C p.I2435T | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.325); catalogued as rs749703843, COSV54124854; called by muse, mutect2, varscan2
- BBS12 | c.1552A>G p.R518G | Missense Mutation (SNP) | VAF 209/496 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV58561394; called by muse, mutect2, varscan2
- BRD4 | c.3588C>G p.I1196M | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99651198; called by muse, varscan2
- F9 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 167/981 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV54378700, COSV54380932; called by muse, mutect2, varscan2
- FAM214B | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as rs765218132, COSV59715013; called by muse, mutect2, varscan2
- GEN1 | c.2663G>C p.G888A | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58055349; called by muse, mutect2, varscan2
- HOXA7 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99636670; called by muse, mutect2
- IWS1 | c.1012_1014del p.K338del | In Frame Del (DEL) | VAF 245/595 reads (41%) | catalogued as COSV54866587; called by mutect2, pindel, varscan2
- KCNJ11 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100217591; called by muse, mutect2, varscan2
- MAP3K15 | c.1333A>C p.N445H | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.921); catalogued as COSV100135373; called by muse, mutect2, varscan2
- MPV17L2 | c.493dup p.Q165Pfs*175 | Frame Shift Ins (INS) | VAF 14/126 reads (11%) | catalogued as rs746591385; called by mutect2, varscan2
- MYO1C | c.1969G>A p.V657M (on ENST00000648651 / NM_001080779.2; = p.V622M on NM_033375.5) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913679893, COSV100704506; called by muse, mutect2
- NR4A3 | c.989C>A p.A330E | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100432836, COSV58243284; called by mutect2, varscan2
- NUP88 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99851899; called by muse, mutect2
- OR5A1 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 1384/2230 reads (62%) | catalogued as rs771050906, COSV57375768; called by muse, mutect2, varscan2
- OR8J1 | c.616A>T p.N206Y | Missense Mutation (SNP) | VAF 87/157 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57316607; called by muse, mutect2, varscan2
- SCN10A | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 113/470 reads (24%) | catalogued as rs763084100, COSV71860285; ClinVar: uncertain significance; called by muse, mutect2
- TPK1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 23/866 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV63640925; called by muse, mutect2
- ZNF181 | c.791C>G p.P264R | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67626286; called by muse, mutect2, varscan2
- ZNF236 | c.1381dup p.M461Nfs*104 | Frame Shift Ins (INS) | VAF 35/47 reads (74%) | catalogued as rs769237443; called by mutect2, varscan2
- ATP11A | c.1374G>A p.S458= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as rs778285031, COSV52106272; called by muse, mutect2, varscan2
- CA6 | c.495C>T p.F165= | Silent (SNP) | VAF 191/608 reads (31%) | catalogued as rs1366948886, COSV66261367; called by muse, mutect2, varscan2
- CAPN6 | c.1905C>T p.S635= | Silent (SNP) | VAF 453/1077 reads (42%) | catalogued as rs921083346, COSV100137003; called by muse, mutect2, varscan2
- CASK | c.2430C>T p.S810= (on ENST00000378163 / NM_001367721.1; = p.S805= on NM_003688.3) | Silent (SNP) | VAF 267/812 reads (33%) | catalogued as COSV59361717; called by muse, mutect2, varscan2
- CHST15 | c.1522T>C p.L508= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV60560233; called by muse, mutect2, varscan2
- COL12A1 | c.207A>G p.E69= | Silent (SNP) | VAF 33/218 reads (15%) | catalogued as COSV59389702; called by muse, mutect2, varscan2
- GABRA4 | c.531G>C p.V177= | Silent (SNP) | VAF 26/211 reads (12%) | catalogued as COSV51922717, COSV51928508; called by muse, mutect2
- KCNJ4 | c.594C>T p.G198= | Silent (SNP) | VAF 34/38 reads (89%) | catalogued as COSV57856152; called by muse, mutect2, varscan2
- KLK10 | c.711G>A p.E237= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100011235; called by muse, mutect2
- SERINC2 | c.912C>T p.N304= (on ENST00000373709 / NM_178865.5; = p.N308= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1443147266, COSV101036736, COSV65489351; called by muse, mutect2, varscan2
- STK40 | c.726C>T p.P242= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs763037189, COSV63734705, COSV63735202; called by muse, mutect2, varscan2
- TKTL2 | c.168G>A p.T56= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs776271739, COSV54917421, COSV99761399; called by muse, mutect2, varscan2
- TRAF3IP2 | c.918G>A p.Q306= | Silent (SNP) | VAF 82/773 reads (11%) | catalogued as COSV60675096; called by muse, mutect2
